Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70I, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70I-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology [C

Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

1. Lymph node, portahepatic, resection (1FS): Reactive lymph node, no tumor seen.
2. Soft tissue, retroperitoneal mass, resection: Consistent with paraganglioma. See Note.
3. Lymph node, site not specified, resection: Lymph node with artifact, no tumor seen.

NOTE: Immunohistochemistry is performed. The tumor cells are positive for chromogranin A, synaptophysin, and CD56. They are negative for inhibin and AE1/AE3. The histological features and immunohistochemical profile support the above diagnosis. Tumor extends to the inked margin.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History:
Suspected paraganglioma Specimen Taken For Protocol:
01 - Yes

PROCEDURE: Pre-Operative Diagnosis: RETroperitoneal mass at the root of the mesentery Post-Operative Diagnosis: RETroperitoneal mass at the root of the mesentery Operative Findings: RETroperitoneal mass at the root of the mesentery
Node, para choledocal

SPECIMENS SUBMITTED: 1. LYMPH NODES, Portahepatic (1FS)
2. RETROPERITONEUM, SMA paraganglioma
3. LYMPH NODES

INTRAOPERATIVE CONSULTATION:

1FS "Portahepatic lymph node frozen section"
1FS diagnosis: Reactive lymph node, no paraganglioma or tumor seen on representative frozen section.

[page 2 of 2]
Frozen section was diagnosed by _____ and _____ on _____.

GROSS DESCRIPTION: Received are 3 containers labeled with the patient's name, medical record number, and further specified as:

1. "Portahepatic lymph node frozen section" consists of a red-tan soft tissue node measuring 1.8 x 1.4 x 0.4 cm. It is bisected and half is frozen as _____. In Surgical Pathology, the frozen sample is transferred to an orange cassette labeled _____. The remainder of the tissue is entirely submitted in white cassettes labeled _____ for permanent processing.

2. "SMA paraganglioma for research and permanent" consists of a tan-pink nodular tissue measuring 5.8 x 4 x 4 cm and weighing 45.3 grams. The specimen has a thin wispy tan capsule which was inked in black. It is bisected revealing a pink-red soft-solid cut surface. Gross photographs are taken. Approximately 50% of tissue is procured for _____ and _____. A piece of the tissue representing the mirror image of the tissue procured is placed into a green cassette labeled "mass mirror image" and placed into formalin along with the remaining half of the specimen for permanent. The procurement was performed by _____ and _____ in _____. In Surgical Pathology, the specimen received matches the above description. The specimen from the green cassette is transferred to white cassette labeled _____ for permanent processing. The remainder of the tissue is serially sectioned. Representative sections are submitted in white cassettes labeled _____ for permanent processing.

3. "Lymph nodes for permanent" consists of a tan-black-yellow soft tissue fragment measuring 0.5 x 0.3 x 0.3 cm. The specimen is entirely submitted in a white cassette labeled _____ for permanent processing.

Gross description dictated by _____.

No consultants

Source: NCI Genomic Data Commons file 90c3c79a-55f8-4908-9e61-118ea7534578 (TCGA-QR-A70I.4243EF14-0AB3-4E1B-8544-1BF841DD0446.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).